Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7402, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7402-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) LARYNX, SUPRAGLOTTIC, BIOPSY: INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

Electronically Signed Out by [REDACTED].

CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) supraglottic larynx

INSTRUCTIONS TO PATHOLOGIST: Routine.

GROSS DESCRIPTION:

1) SOURCE: Supraglottic Larynx

Source #1 is received fresh in a container labeled "supraglottic larynx" and consists multiple irregularly shaped and unoriented fragments which measure in aggregate 1.3 x 1.3 x 0.5 cm. The surfaces of all are inked green and the specimen is entirely submitted within cassette 1A.

Summary of sections: 1A, 4/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file a88726ba-c4be-4f24-a989-39da65927380 (TCGA-CR-7402.8F594ABB-558A-4C43-A991-4EA292110A77.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).